Gene-level copy-number profile of tumor specimen C3L-08145-01 from CPTAC case C3L-08145, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,266 days).
Specimen C3L-08145-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 763421b2-0411-4341-91ee-26ff9b741f16.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08145-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/499578f7-8748-4773-83f6-9bca74b6814b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 352; copy number 2: 54,160; copy number 3: 3,434; copy number 4: 345; copy number 5: 68; copy number 6: 18; copy number 9: 2; copy number 12: 7; copy number 15: 4.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:17,810,979–18,021,876, 3 genes: NCAPG, LCORL, KRT18P63.
- chr14:26,443,090–26,598,033, 2 genes: NOVA1, AL079343.1.
- chr17:22,233,926–22,266,392, 1 gene: LINC02002.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 99 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,851,791–91,723,605, 48 genes, copy number 5: IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2.
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr9:63,703,065–64,413,142, 16 genes, copy number 5: AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P.
- chr9:67,791,499–68,540,883, 16 genes, copy number 6: RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252.
- chr11:54,591,480–54,592,409, 1 gene, copy number 5: OR4C50P.
- chr14:18,333,726–18,419,273, 4 genes, copy number 15: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr19:24,146,701–24,163,425, 2 genes, copy number 6: AC073534.2, AC073534.1.
- chr21:10,482,738–13,120,807, 11 genes, copy number 5–12 (within-gene range 2–12): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
